Somatic mutation profile of tumor specimen TARGET-30-PATWMX-01A (aliquot TARGET-30-PATWMX-01A-01D) from TARGET case TARGET-30-PATWMX, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 1.3 years (462 days).
Specimen TARGET-30-PATWMX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de63534d-4c23-488a-8721-0196f02320ec.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATWMX-10A (Blood Derived Normal), aliquot TARGET-30-PATWMX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51069bb2-40c9-4ae6-b2b6-3b54f6d96418

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2C | c.3795A>T p.E1265D | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV51483169; called by muse, mutect2, varscan2
- NF1 | c.1978A>T p.K660* | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as COSV62214708; called by muse, mutect2, varscan2
- ANKRD30A | c.2739A>G p.S913= (on ENST00000611781; = p.S857= on NM_052997.2) | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV64617415, COSV64618048; called by muse, mutect2, varscan2
- NF1 | c.1977G>T p.R659= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV62214692; called by muse, mutect2, varscan2
